MMRF case MMRF_1565 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/53ae643d-4475-458f-8379-ba595f03003c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 39.2 years (14,330 days); ISS stage: I; Days to last known disease status: 1,281 days (3.5 years); Days to last follow up: 1,281 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 20 days; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 129 days; Days to treatment end: 129 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,183 days (3.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,281.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 108 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.229 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 0 mg/dL.
- Day 104 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL.
- Day 202 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 273 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 521 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 4.57 mmol/L.
- Day 651 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 44.1 g/L; Total Protein 7.9 g/dL; Glucose 5.12 mmol/L.
- Day 759 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 4.73 mmol/L.
- Day 857 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7.8 g/dL; Glucose 5.78 mmol/L.
- Day 975 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.522 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 4.9 mmol/L.
- Day 1,136 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 16.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.866 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 1,210 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 7.36 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 3.91 mmol/L.

Other clinical attributes
- Day 1: Weight: 53 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1565_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1565_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
